FM case AD15007 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas.
https://portal.gdc.cancer.gov/cases/27f85d59-cd6e-47d6-8a50-2396258bf033

Female, 60.5 years: Melanoma, NOS (ICD-O-3 8720/3); specimen biopsied or resected from the vagina. Tumor nuclei on the sequenced sample's slide: 43% (pathologist estimate recorded by GDC). Sample type: Tumor.
